Somatic mutation profile of tumor specimen TCGA-AG-4007-01A (aliquot TCGA-AG-4007-01A-01W-1073-09) from TCGA case TCGA-AG-4007, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 87.0 years (31,776 days).
Specimen TCGA-AG-4007-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6edb8579-d61e-417f-9941-0641c3603cd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-4007-10A (Blood Derived Normal), aliquot TCGA-AG-4007-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f482f6b-b218-47e6-825c-26401e1797d9

The open-access MAF lists 162 somatic variants for this specimen: 118 protein-altering or splice-affecting, 37 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 37, Nonsense Mutation 6, Frame Shift Ins 5, Intron 3, RNA 3, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3907C>T p.Q1303* | Nonsense Mutation (SNP) | VAF 54/256 reads (21%) | hotspot (GDC flag); catalogued as CM994441, COSV57323819; called by muse, mutect2, varscan2
- APC | c.4135G>T p.E1379* | Nonsense Mutation (SNP) | VAF 160/245 reads (65%) | hotspot (GDC flag); catalogued as rs121913326, COSV57320699, COSV57391553; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.13528G>A p.A4510T | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs397516510, CM043079, COSV63693754; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.379T>C p.S127P | Missense Mutation (SNP) | VAF 25/44 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52667433, COSV52678360, COSV52751962; called by muse, mutect2, varscan2
- ABI3 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56800597; called by muse, mutect2, varscan2
- ABRA | c.23G>T p.S8I | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as COSV61732774; called by muse, mutect2, varscan2
- ADAMTS2 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371384169; called by muse, mutect2, varscan2
- ADCY2 | c.2662G>A p.V888I | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57869521; called by muse, mutect2, varscan2
- ADGRE2 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs765071211, COSV59694490; called by mutect2, varscan2
- APLNR | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV57241509, COSV57243178; called by muse, mutect2, varscan2
- AQP7 | c.700dup p.R234Pfs*61 | Frame Shift Ins (INS) | VAF 10/76 reads (13%) | catalogued as rs3215969; called by mutect2, varscan2
- ATP4A | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 98/234 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779456771, COSV52869103; called by muse, mutect2, varscan2
- BBS12 | c.466A>C p.S156R | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV58562366; called by muse, mutect2, varscan2
- BCHE | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as COSV100012259, COSV52258452; called by muse, mutect2, varscan2
- C9orf72 | c.228G>C p.E76D | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.641); catalogued as COSV66154825; called by muse, mutect2, varscan2
- CASP14 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 342/855 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs771317945, COSV55665459, COSV55666814; called by muse, mutect2, varscan2
- CAT | c.1047A>T p.K349N | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53811726; called by muse, mutect2, varscan2
- CFAP97 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs371391407, COSV57111029; called by muse, mutect2, varscan2
- CHD4 | c.3434G>T p.S1145I (on ENST00000357008 / NM_001363606.2; = p.S1158I on NM_001273.5) | Missense Mutation (SNP) | VAF 123/272 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58904385; called by muse, mutect2, varscan2
- CSMD1 | c.160A>T p.N54Y | Missense Mutation (SNP) | VAF 156/251 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68221572; called by muse, mutect2, varscan2
- CSMD2 | c.7909C>T p.R2637C | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs768845179, COSV53917194, COSV99588418; called by muse, mutect2, varscan2
- CSMD3 | c.9877G>T p.D3293Y (on ENST00000297405 / NM_001363185.1; = p.D3124Y on NM_052900.3) | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV52222135, COSV99840531; called by muse, mutect2, varscan2
- CYP21A2 | c.521G>A p.C174Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV64481711; called by muse, mutect2
- DCAF12L2 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as COSV63580157; called by muse, mutect2, varscan2
- DDX4 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as rs757458025, COSV61753971, COSV61754925; called by muse, mutect2
- DISP1 | c.3181C>T p.R1061C | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs371849402; called by muse, mutect2, varscan2
- DNAH10 | c.6590C>T p.T2197M (on ENST00000409039; = p.T2136M on NM_207437.3) | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs372604094; called by muse, mutect2, varscan2
- DSCAML1 | c.3544G>A p.V1182I (on ENST00000321322; = p.V1122I on NM_020693.4) | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.047); catalogued as rs750218765, COSV58389446; called by muse, mutect2, varscan2
- EAPP | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs1333612794, COSV51652203; called by muse, mutect2, varscan2
- EPS8L3 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV62609808; called by muse, mutect2, varscan2
- GJB7 | c.319A>G p.K107E | Missense Mutation (SNP) | VAF 248/681 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV51530314; called by muse, mutect2, varscan2
- GMPPA | c.255A>C p.E85D | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58007432; called by muse, mutect2, varscan2
- GNLY | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs201165294, COSV55704507; called by muse, mutect2, varscan2
- GPC6 | c.1466G>A p.S489N | Missense Mutation (SNP) | VAF 95/194 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs1401371941, COSV65503765, COSV65517573; called by muse, mutect2, varscan2
- GPRASP1 | c.3184T>G p.F1062V | Missense Mutation (SNP) | VAF 367/464 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64355928; called by muse, mutect2, varscan2
- GRM2 | c.2248C>T p.R750C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329180037, COSV56585646; called by muse, mutect2, varscan2
- GRM7 | c.2686G>A p.V896I | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as rs781301094, COSV63150459; called by muse, mutect2, varscan2
- IGFBP3 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as COSV51872817; called by muse, mutect2, varscan2
- KCNC1 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775163829, COSV56391072, COSV56396403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM5B | c.3496A>C p.K1166Q | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV52509370; called by muse, mutect2, varscan2
- LCOR | c.1214G>T p.R405M | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.439); catalogued as COSV63631395; called by muse, mutect2, varscan2
- LYSMD1 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs200029870, COSV54861179; called by muse, mutect2, varscan2
- MGAM | c.71_72insA p.F24Lfs*48 | Frame Shift Ins (INS) | VAF 19/63 reads (30%) | catalogued as COSV71885646; called by mutect2, pindel, varscan2
- MME | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs757277227, COSV100852461, COSV64707933; called by muse, mutect2, varscan2
- MXRA5 | c.5552A>G p.E1851G | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV54239979; called by muse, mutect2, varscan2
- MYH10 | c.2959A>T p.I987F | Missense Mutation (SNP) | VAF 106/311 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as rs1328967664, COSV52604372; called by muse, mutect2, varscan2
- MYH11 | c.1904C>T p.T635M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as rs745878375, COSV55558264; ClinVar: uncertain significance; called by muse, mutect2
- NEK2 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 294/597 reads (49%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs753485254, COSV65356353; called by muse, mutect2, varscan2
- NFATC4 | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 6/9 reads (67%) | catalogued as COSV51605486; called by muse, mutect2, varscan2
- NLRP1 | c.3373G>A p.V1125I | Missense Mutation (SNP) | VAF 91/145 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201871081, COSV52569601; called by muse, mutect2, varscan2
- NOVA2 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV54358309; called by muse, mutect2, varscan2
- NRG3 | c.1822G>T p.E608* (on ENST00000404547 / NM_001370084.1; = p.E584* on NM_001010848.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 108/223 reads (48%) | catalogued as COSV64559252, COSV64569676; called by muse, mutect2, varscan2
- NUS1 | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 92/324 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV63844373; called by muse, mutect2, varscan2
- NWD1 | c.2782G>T p.A928S | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as COSV60344905; called by muse, mutect2, varscan2
- OTOGL | c.4544G>A p.R1515Q (on ENST00000547103; = p.R1506Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs201232946; called by muse, mutect2, varscan2
- PAK3 | c.1657G>A p.A553T (on ENST00000262836 / NM_001324328.2; = p.A538T on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV53269913, COSV53276515; called by muse, mutect2, varscan2
- PATJ | c.3023G>C p.R1008T | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV57165325; called by muse, mutect2, varscan2
- PCDH17 | c.1066G>A p.V356M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV64975661; called by muse, mutect2, varscan2
- PCDHB6 | c.2150C>A p.A717E | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.823); catalogued as COSV50704040; called by muse, mutect2, varscan2
- PCDHGA11 | c.1975G>A p.V659I | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.474); catalogued as rs771252840, COSV53898850; called by muse, mutect2, varscan2
- PCF11 | c.2572G>T p.G858* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | catalogued as COSV53533513; called by muse, mutect2, varscan2
- PHIP | c.3326A>C p.N1109T | Missense Mutation (SNP) | VAF 135/351 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV51506420, COSV99244891; called by muse, mutect2, varscan2
- PLEK | c.392T>C p.L131S | Missense Mutation (SNP) | VAF 111/563 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV52252568; called by muse, mutect2, varscan2
- POLR2B | c.3346G>A p.V1116I | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV55274114, COSV55274330; called by muse, mutect2, varscan2
- POLR3E | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 10/16 reads (63%) | catalogued as COSV55401580; called by muse, mutect2
- PPP1R12A | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs752612405, COSV54106433; called by muse, mutect2, varscan2
- PSD2 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as rs549742335, COSV51197107; called by muse, mutect2, varscan2
- RAB39A | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs1367462296, COSV57694535; called by muse, mutect2, varscan2
- RALGAPA1 | c.5725G>A p.V1909I | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV51887607; called by muse, mutect2, varscan2
- RIMBP3 | c.3232T>C p.F1078L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as rs1371935377; called by mutect2, varscan2
- ROBO1 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs754092395, COSV71394997, COSV71396072; called by muse, mutect2, varscan2
- RRP9 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as rs374405922; called by muse, mutect2
- SCN4A | c.2038G>T p.A680S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV71127467; called by mutect2, varscan2
- SCN4A | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs538978403, COSV71127470; called by muse, mutect2, varscan2
- SCN5A | c.4057G>A p.V1353M (on ENST00000333535 / NM_198056.3; = p.V1352M on NM_000335.5) | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs199473233, CM100708, COSV61114948; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- SCN7A | c.1791A>T p.L597F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as COSV69272708; called by muse, mutect2
- SCYL2 | c.1298T>A p.M433K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV62569427; called by muse, mutect2, varscan2
- SIGLECL1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 130/349 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs149546733; called by muse, mutect2, varscan2
- SLC2A7 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV68901982; called by muse, mutect2, varscan2
- SLC30A9 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs144935504; called by muse, mutect2, varscan2
- SLC4A8 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs374704511; called by muse, mutect2, varscan2
- SLITRK6 | c.1224G>T p.M408I | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV68389510, COSV68390569; called by muse, mutect2, varscan2
- SOGA3 | c.2368C>T p.R790C | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs1324685516, COSV64105666; called by muse, mutect2, varscan2
- SORCS1 | c.2060G>A p.G687E | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1365630409, COSV53877805; called by muse, mutect2, varscan2
- SRPRB | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV53314379; called by muse, mutect2, varscan2
- ST8SIA4 | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 102/177 reads (58%) | PolyPhen benign (0.049); catalogued as COSV51512095; called by muse, mutect2, varscan2
- SUCNR1 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 111/451 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.921); catalogued as COSV62912475; called by muse, mutect2, varscan2
- TENM4 | c.6502G>A p.V2168I | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.972); catalogued as rs200474747; called by muse, mutect2, varscan2
- TMEM169 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 166/836 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as rs770002384, COSV55265718; called by muse, mutect2, varscan2
- TMEM41A | c.467dup p.L158Ifs*40 | Frame Shift Ins (INS) | VAF 54/240 reads (23%) | catalogued as rs758476632; called by mutect2, varscan2
- TMIGD2 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV56667562, COSV56668501; called by muse, mutect2, varscan2
- TNFAIP6 | c.244T>C p.C82R | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54641476; called by muse, mutect2
- TNXB | c.6365C>T p.P2122L (on ENST00000647633; = p.P1875L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs1404360124, COSV64481718; called by muse, mutect2, varscan2
- TRBC2 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs782337323; called by muse, mutect2, varscan2
- TRO | c.2624C>T p.T875M | Missense Mutation (SNP) | VAF 81/100 reads (81%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as rs748992156, COSV51499283; called by muse, mutect2, varscan2
- TSC22D4 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV55724579; called by muse, mutect2, varscan2
- TSPYL6 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.94); catalogued as rs757162814, COSV57816578; called by muse, mutect2, varscan2
- TTI1 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 122/513 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs763501723, COSV65060777, COSV65060974; called by muse, mutect2, varscan2
- UBE2E2 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59972737; called by muse, mutect2, varscan2
- UBN2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746848105, COSV56031400, COSV99944221; called by muse, mutect2, varscan2
- UGGT1 | c.2303A>G p.D768G | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489586107, COSV52137753; called by muse, mutect2, varscan2
- VPS13A | c.4403C>T p.A1468V | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as COSV62432410; called by muse, mutect2, varscan2
- WDR17 | c.3874G>A p.G1292R | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs146320284; called by muse, mutect2
- ZC3H15 | c.1216C>G p.L406V | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV61922253, COSV61922765; called by muse, mutect2, varscan2
- ZC3H7B | c.1531G>A p.V511M | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750052358, COSV60962111; called by muse, mutect2, varscan2
- ZDBF2 | c.5273C>A p.S1758Y | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV65627445; called by muse, mutect2, varscan2
- ZNF112 | c.1417C>T p.R473C (on ENST00000337401 / NM_001083335.2; = p.R467C on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 138/313 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202199443, COSV61620772; called by muse, mutect2, varscan2
- ZNF471 | c.67T>C p.F23L | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV57292016; called by muse, mutect2, varscan2
- ZP3 | c.474G>T p.L158F (on ENST00000394857 / NM_001110354.2; = p.L107F on NM_007155.6) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV60633970; called by muse, mutect2, varscan2
- ZSCAN5B | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.994); catalogued as COSV62839964; called by muse, mutect2, varscan2
- ZSWIM3 | c.1275C>A p.F425L | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV54845066, COSV54848796; called by muse, mutect2, varscan2
- ZSWIM3 | c.1555A>T p.N519Y | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV54848803; called by muse, mutect2
- DNAJC5G | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.023); called by mutect2, varscan2
- EML4 | c.560dup p.N187Kfs*4 | Frame Shift Ins (INS) | VAF 24/125 reads (19%) | called by mutect2, pindel, varscan2
- GOLGA6L9 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.914); called by muse, mutect2
- GOLGA6L9 | c.446C>A p.A149D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); called by muse, mutect2
- ITGA8 | c.2798_2800del p.S933del | In Frame Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel, varscan2
- TNS3 | c.3257dup p.Q1088Pfs*13 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | called by mutect2, varscan2
- APBA1 | c.2412C>T p.I804= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as rs778881943, COSV55225402; called by muse, mutect2, varscan2
- ARAP1 | c.762G>A p.P254= (on ENST00000393609 / NM_001040118.2; = p.P9= on NM_015242.4) | Silent (SNP) | VAF 28/197 reads (14%) | catalogued as rs775665816, COSV61990803; called by muse, varscan2
- CCDC173 | c.1440A>G p.E480= | Silent (SNP) | VAF 113/589 reads (19%) | catalogued as COSV53644014; called by muse, mutect2, varscan2
- CCNJL | c.867G>A p.T289= | Silent (SNP) | VAF 239/322 reads (74%) | catalogued as rs544092120, COSV57444864; called by muse, mutect2, varscan2
- CCNT1 | c.1782T>C p.S594= | Silent (SNP) | VAF 36/188 reads (19%) | catalogued as COSV56064853; called by muse, mutect2, varscan2
- CKM | c.324T>C p.T108= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as rs750179345, COSV55533765; called by muse, mutect2, varscan2
- CLCN1 | c.2469G>A p.Q823= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as rs750945292, COSV58370943, COSV58371214; called by muse, mutect2, varscan2
- CTLA4 | c.516G>A p.S172= | Silent (SNP) | VAF 79/521 reads (15%) | catalogued as rs375949600; called by muse, mutect2, varscan2
- GPR101 | c.714C>A p.V238= | Silent (SNP) | VAF 53/223 reads (24%) | catalogued as COSV53239360; called by muse, mutect2, varscan2
- ISLR2 | c.768C>T p.F256= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs767798618, COSV62302606, COSV62304234; called by muse, mutect2, varscan2
- LRP1B | c.9261G>A p.A3087= | Silent (SNP) | VAF 41/118 reads (35%) | catalogued as rs749167039, COSV67232812, COSV67239762; called by muse, mutect2, varscan2
- LRRC55 | c.744C>T p.A248= | Silent (SNP) | VAF 56/153 reads (37%) | catalogued as COSV73006671; called by muse, mutect2, varscan2
- MED12L | c.6426T>G p.P2142= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV56384380; called by muse, mutect2, varscan2
- MUC16 | c.19797C>T p.T6599= | Silent (SNP) | VAF 117/662 reads (18%) | catalogued as COSV67475882; called by muse, mutect2, varscan2
- OCM | c.165G>A p.Q55= | Silent (SNP) | VAF 233/412 reads (57%) | catalogued as COSV54194626; called by muse, mutect2, varscan2
- OSR1 | c.246G>A p.A82= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV55344851; called by muse, mutect2, varscan2
- PAIP2 | c.195G>A p.L65= | Silent (SNP) | VAF 85/132 reads (64%) | catalogued as COSV54525413; called by muse, mutect2, varscan2
- PCDHA7 | c.1281G>A p.A427= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as rs782671878, COSV65348636; called by muse, mutect2, varscan2
- RASAL2 | c.159G>A p.R53= | Silent (SNP) | VAF 22/152 reads (14%) | catalogued as rs1252609181, COSV62711751, COSV62716546; called by muse, mutect2, varscan2
- SH2B3 | c.1659G>A p.S553= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs369151728, COSV57984346; called by muse, mutect2, varscan2
- SLC9B1 | c.405G>A p.T135= | Silent (SNP) | VAF 42/248 reads (17%) | catalogued as rs749251463, COSV56471830; called by muse, mutect2, varscan2
- SP140L | c.1233C>T p.D411= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as rs760421071, COSV54745025; called by muse, mutect2, varscan2
- TBX22 | c.135G>A p.E45= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV64786681, COSV64786961; called by muse, mutect2
- TENM3 | c.5403C>T p.Y1801= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs758457707, COSV69312058; called by muse, mutect2, varscan2
- TRIB2 | c.402T>C p.Y134= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV50227000; called by muse, mutect2, varscan2
- TRPC1 | c.1893C>T p.V631= (on ENST00000476941 / NM_001251845.2; = p.V597= on NM_003304.4) | Silent (SNP) | VAF 67/264 reads (25%) | catalogued as rs1360411238, COSV56426799; called by muse, mutect2, varscan2
- TTN | c.21594C>A p.P7198= (on ENST00000591111; = p.P6271= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 142/374 reads (38%) | catalogued as COSV60153327; called by muse, mutect2, varscan2
- VRK1 | c.234A>C p.G78= | Silent (SNP) | VAF 64/163 reads (39%) | catalogued as COSV53710070; called by muse, mutect2, varscan2
- VWA8 | c.3993A>C p.I1331= | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as COSV64997759; called by muse, mutect2, varscan2
- WASHC2C | c.3159C>T p.S1053= (on ENST00000336378; = p.S1032= on NM_015262.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 31/124 reads (25%) | called by muse, mutect2, varscan2
- WDR88 | c.669C>T p.S223= | Silent (SNP) | VAF 76/191 reads (40%) | catalogued as rs144975503; called by muse, mutect2, varscan2
- XKR4 | c.1671C>T p.S557= | Silent (SNP) | VAF 139/200 reads (70%) | catalogued as COSV59323374; called by muse, mutect2, varscan2
- ZC3H8 | c.585A>G p.Q195= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV55619825; called by muse, mutect2, varscan2
- ZNF318 | c.2241T>A p.S747= | Silent (SNP) | VAF 52/246 reads (21%) | catalogued as COSV58934021; called by muse, mutect2, varscan2
- ZNF674 | c.1401A>G p.K467= | Silent (SNP) | VAF 89/257 reads (35%) | called by muse, mutect2, varscan2
- ZNF70 | c.663G>A p.K221= | Silent (SNP) | VAF 40/193 reads (21%) | catalogued as rs756976286, COSV59533247; called by muse, mutect2, varscan2
- ZNF846 | c.1413G>A p.T471= | Silent (SNP) | VAF 102/277 reads (37%) | catalogued as rs377731453; called by muse, mutect2, varscan2
- CACNB2 | c.804+665G>A | Intron (SNP) | VAF 39/139 reads (28%) | catalogued as rs373932682, COSV56632783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSH1 | c.457-35C>T | Intron (SNP) | VAF 36/223 reads (16%) | catalogued as rs749564716, COSV60241902; called by muse, mutect2, varscan2
- DCHS2 | n.6759G>C | RNA (SNP) | VAF 107/223 reads (48%) | catalogued as COSV61767411, COSV61774393; called by muse, mutect2, varscan2
- MASP1 | c.1303+4931C>T | Intron (SNP) | VAF 14/65 reads (22%) | catalogued as rs776846809, COSV56224900; called by muse, mutect2, varscan2
- MIR514A3 | n.44A>G | RNA (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163856 C>A | 5'Flank (SNP) | VAF 21/126 reads (17%) | called by muse, mutect2, varscan2
- SNORD116-12 | n.67C>A | RNA (SNP) | VAF 101/203 reads (50%) | catalogued as rs756299298; called by muse, mutect2, varscan2
